Somatic mutation profile of tumor specimen 2563cb02-d58a-4286-8634-7502cd (aliquot 2563cb02-d58a-4286-8634-7502cd_D6) from CPTAC case 17OV034, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 2563cb02-d58a-4286-8634-7502cd: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcdac999-62a5-4258-b01d-44f106dd3919.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 5918ebb7-1c63-407a-bf01-af3f09 (Blood Derived Normal), aliquot 5918ebb7-1c63-407a-bf01-af3f09_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7e84a04-c06e-410d-9b8d-eaeee8ebe314

The open-access MAF lists 91 somatic variants for this specimen: 67 protein-altering or splice-affecting, 11 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 11, Intron 7, Frame Shift Del 4, Splice Site 3, 3'UTR 2, Nonsense Mutation 2, 5'Flank 2, In Frame Del 1, RNA 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.635_636del p.F212Sfs*3 | Frame Shift Del (DEL) | VAF 217/565 reads (38%) | catalogued as rs864309495; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ANP32A | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 68/171 reads (40%) | catalogued as COSV51189644; called by muse, mutect2, varscan2
- BPIFB6 | c.745T>A p.Y249N | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as COSV62755692; called by muse, mutect2, varscan2
- CFAP46 | c.3886C>T p.R1296W | Missense Mutation (SNP) | VAF 98/219 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs781456529; called by muse, mutect2, varscan2
- COL20A1 | c.2906G>A p.S969N | Missense Mutation (SNP) | VAF 15/264 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs757526959; called by muse, mutect2
- EML4 | c.1038G>T p.W346C | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59296481; called by muse, mutect2, varscan2
- FAF1 | c.601C>G p.R201G | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.274); catalogued as rs750382332; called by muse, mutect2, varscan2
- FSD1 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 68/326 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376221601; called by muse, mutect2
- GPR83 | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 132/450 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54720725; called by muse, mutect2, varscan2
- IGSF3 | c.1405G>A p.V469M (on ENST00000369486 / NM_001007237.3; = p.V489M on NM_001542.4) | Missense Mutation (SNP) | VAF 162/510 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs746850956, COSV59585506; called by muse, mutect2, varscan2
- IL27 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs750265879, COSV60489049; called by muse, mutect2, varscan2
- LRRC18 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 129/349 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as rs138127999; called by muse, mutect2, varscan2
- LRTM2 | c.325C>G p.R109G | Missense Mutation (SNP) | VAF 170/530 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs979717837; called by muse, mutect2, varscan2
- PDE4A | c.754C>A p.R252S | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV53351337; called by muse, mutect2, varscan2
- PLEC | c.2771G>A p.R924Q (on ENST00000322810 / NM_201380.4; = p.R814Q on NM_000445.5) | Missense Mutation (SNP) | VAF 144/693 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs1319068044, COSV59632795; called by muse, mutect2, varscan2
- RTP5 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 107/234 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.101); catalogued as rs780529807; called by muse, mutect2, varscan2
- SH3TC2 | c.2711G>A p.R904Q | Missense Mutation (SNP) | VAF 500/809 reads (62%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs773922490, COSV100102522, COSV60462248; called by muse, mutect2, varscan2
- SOCS6 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 27/526 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as COSV67547381; called by muse, mutect2
- TEX15 | c.5616C>A p.N1872K (on ENST00000256246; = p.N2255K on NM_001350162.2) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as COSV99821668; called by muse, mutect2, varscan2
- TSPAN16 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1272019166, COSV57442449; called by muse, mutect2, varscan2
- YEATS2 | c.1628G>T p.G543V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs1367843284; called by muse, mutect2, varscan2
- ADAM10 | c.104T>C p.L35S | Missense Mutation (SNP) | VAF 82/322 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADAM32 | c.53G>C p.R18T | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- AFF1 | c.725C>G p.P242R | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.865); called by muse, mutect2
- AL121899.2 | c.506C>A p.A169D | Missense Mutation (SNP) | VAF 93/282 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGEF10L | c.3158C>T p.A1053V | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AVPI1 | c.185C>G p.A62G | Missense Mutation (SNP) | VAF 111/449 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.96); called by muse, mutect2
- BCAS1 | c.1695G>A p.M565I | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CCDC186 | c.554A>C p.N185T | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CRHR1 | c.241+1G>C p.X81_splice | Splice Site (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- EPB41L1 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 133/429 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- EPC2 | c.2185A>T p.N729Y | Missense Mutation (SNP) | VAF 70/131 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- FNDC1 | c.4152A>C p.K1384N | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- FNDC1 | c.5306C>T p.P1769L | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPATCH8 | c.2996del p.P999Lfs*110 | Frame Shift Del (DEL) | VAF 199/399 reads (50%) | called by mutect2, pindel, varscan2
- HELZ | c.4103G>A p.R1368K | Missense Mutation (SNP) | VAF 21/442 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); called by muse, mutect2
- HSD3B2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 163/564 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- KIAA1958 | c.940A>C p.T314P | Missense Mutation (SNP) | VAF 90/399 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, varscan2
- KIF2C | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MACF1 | c.1754A>G p.N585S | Missense Mutation (SNP) | VAF 138/452 reads (31%) | called by muse, mutect2, varscan2
- NAA10 | c.329A>G p.H110R | Missense Mutation (SNP) | VAF 111/262 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- NBPF14 | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.976); called by mutect2, varscan2
- NCAN | c.2175C>G p.S725R | Missense Mutation (SNP) | VAF 94/286 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NKAIN3 | c.387T>A p.D129E | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.45); called by muse, mutect2
- NRBP2 | c.974A>G p.Y325C | Missense Mutation (SNP) | VAF 93/240 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NRK | c.3215G>A p.S1072N | Missense Mutation (SNP) | VAF 105/238 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- NSD3 | c.320G>T p.S107I | Missense Mutation (SNP) | VAF 12/367 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.23); called by muse, mutect2
- OCIAD1 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.191); called by muse, mutect2
- PAPSS2 | c.521-2A>C p.X174_splice | Splice Site (SNP) | VAF 126/354 reads (36%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.1942G>C p.D648H | Missense Mutation (SNP) | VAF 250/438 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCGF5 | c.383A>T p.D128V | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PIK3R3 | c.290_304del p.Q97_T101del | In Frame Del (DEL) | VAF 27/78 reads (35%) | called by pindel, varscan2
- PLEKHG1 | c.540_541del p.C180* | Frame Shift Del (DEL) | VAF 21/107 reads (20%) | called by pindel, varscan2
- PRG4 | c.812C>G p.S271C | Missense Mutation (SNP) | VAF 18/389 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RAB3GAP2 | c.3205G>A p.A1069T | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- REXO1 | c.1712A>G p.K571R | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, varscan2
- SLAMF9 | c.174C>G p.H58Q | Missense Mutation (SNP) | VAF 146/505 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SLC35G2 | c.587C>A p.T196N | Missense Mutation (SNP) | VAF 173/829 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- SLITRK6 | c.583T>A p.L195I | Missense Mutation (SNP) | VAF 19/293 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPARC | c.452-5_486del p.X151_splice | Splice Site (DEL) | VAF 108/274 reads (39%) | called by mutect2, pindel, varscan2
- SV2C | c.2164C>T p.R722* | Nonsense Mutation (SNP) | VAF 77/116 reads (66%) | called by muse, mutect2, varscan2
- TMC2 | c.1622T>C p.I541T | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TMPRSS13 | c.1376C>G p.T459R | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRIM64B | c.1016A>C p.K339T | Missense Mutation (SNP) | VAF 240/1496 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- TTN | c.51013G>A p.V17005I (on ENST00000591111; = p.V9581I on NM_003319.4) | Missense Mutation (SNP) | VAF 98/329 reads (30%) | PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ZNF689 | c.826_869del p.A277Pfs*60 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- ZNFX1 | c.3106C>T p.L1036= | Splice Region (SNP) | VAF 35/111 reads (32%) | called by muse, mutect2, varscan2
- CHAF1A | c.2286C>G p.R762= | Silent (SNP) | VAF 70/239 reads (29%) | called by muse, mutect2, varscan2
- CX3CL1 | c.414G>T p.L138= | Silent (SNP) | VAF 77/206 reads (37%) | called by muse, mutect2, varscan2
- NCOA3 | c.684C>A p.A228= | Silent (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2, varscan2
- NEK6 | c.390C>T p.L130= | Silent (SNP) | VAF 44/146 reads (30%) | catalogued as rs746266033; called by muse, mutect2, varscan2
- OR6C68 | c.99C>T p.Y33= | Silent (SNP) | VAF 56/172 reads (33%) | catalogued as rs1216323343; called by muse, mutect2, varscan2
- ORAI3 | c.645G>A p.A215= | Silent (SNP) | VAF 184/592 reads (31%) | catalogued as rs779863431, COSV52694071; called by mutect2, varscan2
- PCDH10 | c.2385A>G p.V795= | Silent (SNP) | VAF 162/605 reads (27%) | called by muse, varscan2
- TECPR1 | c.483G>T p.R161= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as rs77272847, COSV65784416; called by muse, mutect2, varscan2
- TMEM86B | c.28C>T p.L10= | Silent (SNP) | VAF 56/133 reads (42%) | called by muse, mutect2, varscan2
- TUSC3 | c.441T>C p.S147= | Silent (SNP) | VAF 70/174 reads (40%) | called by muse, mutect2, varscan2
- ZC3H3 | c.228C>T p.L76= | Silent (SNP) | VAF 145/713 reads (20%) | catalogued as rs754771636; called by muse, mutect2, varscan2
- ABHD14A | c.397+304G>A | Intron (SNP) | VAF 12/21 reads (57%) | catalogued as rs1185951629; called by muse, mutect2, varscan2
- ARHGDIA | c.*363G>A | 3'UTR (SNP) | VAF 83/132 reads (63%) | catalogued as rs1030017053; called by muse, mutect2, varscan2
- BRD2 | c.-889G>C | 5'UTR (SNP) | VAF 56/195 reads (29%) | called by muse, varscan2
- FBXL21P | n.975-450T>G | Intron (SNP) | VAF 49/97 reads (51%) | called by muse, mutect2, varscan2
- IVD | c.243+20C>T | Intron (SNP) | VAF 234/409 reads (57%) | called by muse, mutect2, varscan2
- KIAA1549L | chr11:33542043 del CCAAGGAAGCGGACATAGCGCCTCCCTCGAACCTT | 5'Flank (DEL) | VAF 73/227 reads (32%) | called by mutect2, varscan2
- KNG1 | c.*1405G>C | 3'UTR (SNP) | VAF 15/418 reads (4%) | called by muse, mutect2
- NBR1 | c.1750+32C>A | Intron (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- OFCC1 | n.117C>A | RNA (SNP) | VAF 17/254 reads (7%) | called by muse, mutect2
- PLOD1 | c.77-3427C>T | Intron (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- RNY4P30 | chr13:49892499 G>A | 5'Flank (SNP) | VAF 57/136 reads (42%) | called by muse, mutect2, varscan2
- SLC7A10 | c.1017-36G>T | Intron (SNP) | VAF 99/302 reads (33%) | called by muse, mutect2, varscan2
- ZNF273 | c.103-502A>C | Intron (SNP) | VAF 34/107 reads (32%) | called by muse, mutect2, varscan2
